Somatic mutation profile of tumor specimen TCGA-44-3917-01A (aliquot TCGA-44-3917-01A-01D-A271-08) from TCGA case TCGA-44-3917, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 33.3 years (12,179 days).
Specimen TCGA-44-3917-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70e49dda-c41a-492b-b841-ef3155c006a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-3917-10A (Blood Derived Normal), aliquot TCGA-44-3917-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cce0f20b-ae33-43f3-9b5c-583d02611eea

The open-access MAF lists 236 somatic variants for this specimen: 178 protein-altering or splice-affecting, 53 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 53, Nonsense Mutation 14, Splice Site 5, Frame Shift Del 3, 5'UTR 2, Intron 2, RNA 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ACOT4 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV100412783; called by muse, mutect2, varscan2
- ADAMTS14 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs1205242029, COSV100941385, COSV64605277; called by muse, mutect2, varscan2
- ADAMTS15 | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143111; called by muse, mutect2, varscan2
- ADCY6 | c.865-1G>A p.X289_splice | Splice Site (SNP) | VAF 4/56 reads (7%) | catalogued as rs1471933477, COSV100326413; called by muse, mutect2
- ADRB2 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV100019096; called by muse, mutect2, varscan2
- AFAP1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); catalogued as rs936347149, COSV61800251; called by muse, mutect2, varscan2
- AFF3 | c.3049G>T p.A1017S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417827; called by muse, mutect2, varscan2
- AGTR1 | c.1077G>T p.E359D | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as COSV100836933; called by muse, mutect2, varscan2
- AHNAK2 | c.13079G>T p.G4360V | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.91); catalogued as COSV100315734; called by muse, mutect2, varscan2
- AHNAK2 | c.4996C>A p.P1666T | Missense Mutation (SNP) | VAF 104/470 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100315735; called by muse, mutect2, varscan2
- ALPK2 | c.4825C>T p.P1609S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as COSV100864136; called by muse, mutect2, varscan2
- ANO4 | c.2759A>T p.E920V (on ENST00000392977 / NM_001286615.2; = p.E885V on NM_178826.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152056; called by muse, mutect2, varscan2
- APOB | c.9914C>A p.P3305Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263767; called by muse, mutect2, varscan2
- ARFGEF1 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 61/149 reads (41%) | catalogued as COSV99141127; called by muse, mutect2, varscan2
- ATP5MC1 | c.297-2A>T p.X99_splice | Splice Site (SNP) | VAF 56/198 reads (28%) | catalogued as COSV100582370; called by muse, mutect2, varscan2
- AXDND1 | c.475G>C p.G159R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV100858252; called by muse, mutect2, varscan2
- BCKDHA | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99524439; called by muse, mutect2, varscan2
- BMP6 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.454); catalogued as COSV99306359; called by muse, mutect2, varscan2
- BTN2A2 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100760240; called by muse, mutect2, varscan2
- C9orf131 | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV100397926; called by muse, mutect2, varscan2
- CACNA1E | c.2612G>A p.R871K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100701295; called by muse, mutect2
- CACNA1E | c.6562G>T p.G2188* (on ENST00000367573 / NM_001205293.3; = p.G2145* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100701296, COSV62389009; called by muse, mutect2
- CACNA2D1 | c.3299A>C p.H1100P (on ENST00000356253 / NM_001366867.1; = p.H1088P on NM_000722.4) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100665981; called by muse, mutect2, varscan2
- CBLL2 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100081471; called by muse, mutect2, varscan2
- CCDC144A | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100501951; called by muse, mutect2, varscan2
- CCDC150 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99776533; called by muse, mutect2, varscan2
- CCDC190 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as COSV100905804; called by muse, mutect2
- CCDC43 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV100188901; called by muse, mutect2, varscan2
- CD209 | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV52653411, COSV99213676; called by muse, mutect2, varscan2
- CD3D | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV99416471; called by muse, mutect2, varscan2
- CFHR4 | c.1049C>T p.S350F (on ENST00000367416 / NM_001201551.2; = p.S104F on NM_006684.5) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs1338727661, COSV52229475, COSV99259586; called by muse, mutect2, varscan2
- CLMP | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV101507376; called by muse, mutect2, varscan2
- COL11A1 | c.4972G>T p.V1658L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100615262, COSV62186795; called by muse, mutect2, varscan2
- COL11A1 | c.2974C>G p.P992A | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100615263; called by muse, mutect2, varscan2
- COL12A1 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs370256196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs182278784, COSV64632339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A6 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858652, COSV57872087; called by muse, mutect2
- CORO1C | c.630+1G>T p.X210_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99775744; called by muse, mutect2
- CORO1C | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99775749; called by muse, mutect2
- COTL1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV52290024, COSV99296949; called by muse, mutect2
- CPA4 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55985376; called by muse, mutect2, varscan2
- CPS1 | c.2073G>T p.L691F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as COSV99242249; called by muse, mutect2, varscan2
- CPT1C | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.222); catalogued as COSV99773250, COSV99773319; called by muse, mutect2, varscan2
- CSNK1G3 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100631332; called by muse, mutect2, varscan2
- CYFIP2 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV100555679; called by muse, mutect2, varscan2
- CYP4V2 | c.1467G>A p.W489* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101114748; called by muse, mutect2, varscan2
- CYP7A1 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV100052177; called by muse, mutect2, varscan2
- DHX8 | c.2342C>G p.T781S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291938; called by muse, mutect2, varscan2
- DIP2B | c.4069C>T p.P1357S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99997940; called by muse, mutect2, varscan2
- DNAH10 | c.6830G>T p.G2277V (on ENST00000409039; = p.G2216V on NM_207437.3) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101292002; called by muse, mutect2
- DNAH7 | c.10054G>A p.D3352N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100413907; called by muse, mutect2, varscan2
- DNAH8 | c.7933G>C p.V2645L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV100543408; called by muse, mutect2, varscan2
- DOCK10 | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99287724; called by muse, mutect2, varscan2
- DZIP1 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100714009, COSV100714117; called by muse, mutect2, varscan2
- EDDM3B | c.442T>C p.*148Qext*18 | Nonstop Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100460759; called by muse, mutect2, varscan2
- EIF3E | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV55201312, COSV99622827; called by muse, varscan2
- EYS | c.863-1G>T p.X288_splice | Splice Site (SNP) | VAF 33/105 reads (31%) | catalogued as COSV100675699; called by muse, mutect2, varscan2
- F5 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100888918; called by muse, mutect2
- FAM186B | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV99217986; called by muse, mutect2, varscan2
- FAT4 | c.10380G>T p.Q3460H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV58691084; called by muse, mutect2, varscan2
- FBN2 | c.4339T>C p.C1447R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99325134; called by muse, mutect2, varscan2
- FOXI2 | c.572T>C p.F191S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100510940; called by muse, mutect2, varscan2
- G6PD | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs137852337, CM920289, COSV100854937; called by muse, mutect2, varscan2
- GABRA3 | c.1282C>G p.P428A | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374567584, COSV100942442, COSV64800051; called by muse, mutect2, varscan2
- GATAD2A | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382309211, COSV53067733, COSV99389659; called by muse, mutect2, varscan2
- GON4L | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99673366; called by muse, mutect2, varscan2
- GPR78 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs767824059, COSV101223998, COSV66763165; called by muse, mutect2, varscan2
- GRIN2B | c.3592G>T p.E1198* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as rs1555102052, COSV101662917; called by muse, mutect2, varscan2
- GTPBP10 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745673; called by muse, mutect2, varscan2
- HPS1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100282350; called by muse, mutect2, varscan2
- HUWE1 | c.7903A>T p.T2635S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99470733; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.078); catalogued as COSV56263011; called by muse, mutect2, varscan2
- ITGAX | c.1842G>T p.R614S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99191453; called by muse, mutect2, varscan2
- KCNH5 | c.2416G>T p.G806* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as COSV100525445, COSV59777864; called by muse, mutect2, varscan2
- KCNK10 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100067089; called by muse, mutect2, varscan2
- KCNK13 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99965512; called by muse, mutect2, varscan2
- KCNS2 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99750729; called by muse, mutect2, varscan2
- KEAP1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407360; called by muse, mutect2, varscan2
- KEL | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747360606, COSV100786873; called by muse, mutect2, varscan2
- KERA | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV99899316; called by muse, mutect2, varscan2
- KIF5A | c.2538G>C p.Q846H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54053525, COSV99672469; called by muse, mutect2
- KLHL1 | c.2087G>T p.C696F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100917022; called by muse, mutect2, varscan2
- LAMA2 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV101370109; called by muse, mutect2, varscan2
- LCP1 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100549711, COSV59942701; called by muse, mutect2, varscan2
- LECT2 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.188); catalogued as COSV99191814, COSV99191844; called by muse, mutect2, varscan2
- LGR5 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs767708854, COSV99877538; called by muse, mutect2, varscan2
- LINGO2 | c.1376G>T p.R459I | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430177; called by muse, mutect2, varscan2
- LRP1 | c.7752G>T p.W2584C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99674563; called by muse, mutect2, varscan2
- LRP6 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99742435; called by muse, mutect2, varscan2
- MAN2A1 | c.3431G>T p.R1144M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99810487; called by muse, mutect2, varscan2
- MCM3AP | c.3799C>T p.P1267S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199243662, COSV99386502; called by muse, mutect2
- MCTP2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV100537224, COSV59146121; called by muse, mutect2, varscan2
- MEFV | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99560299; called by muse, mutect2, varscan2
- MLPH | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221837; called by muse, mutect2, varscan2
- MOCOS | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99732836; called by muse, mutect2, varscan2
- MYH1 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99874971; called by muse, mutect2, varscan2
- NAV3 | c.1908-1G>T p.X636_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99887176; called by muse, mutect2, varscan2
- NELL1 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.885); catalogued as COSV100119195, COSV54265162; called by muse, mutect2, varscan2
- NELL1 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV54290586; called by muse, mutect2, varscan2
- NIT1 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100919028; called by muse, mutect2, varscan2
- NTRK1 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.974); catalogued as rs774654606, COSV62323476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OASL | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99984428; called by muse, mutect2, varscan2
- ODF3L1 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100150699; called by muse, mutect2, varscan2
- OR11H12 | c.490T>A p.W164R | Missense Mutation (SNP) | VAF 29/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101612459; called by muse, mutect2
- OR1S2 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100224025; called by muse, mutect2, varscan2
- OR2T6 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100861486; called by muse, mutect2, varscan2
- OR4C46 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as rs776942943, COSV100060417, COSV100060471; called by muse, mutect2, varscan2
- OR51V1 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100343238; called by muse, mutect2, varscan2
- OR52K1 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV100297585, COSV56903770; called by muse, mutect2, varscan2
- OR7G3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV59641431; called by muse, mutect2, varscan2
- OR8G5 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100422232; called by muse, mutect2, varscan2
- OTOF | c.2663C>G p.T888R (on ENST00000272371 / NM_194248.3; = p.T141R on NM_004802.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs766595357, COSV99716629, COSV99718786; called by muse, mutect2, varscan2
- P3H1 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99354849; called by muse, mutect2, varscan2
- PANX3 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs751256451, COSV99421110; called by muse, mutect2, varscan2
- PAOX | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs747718413, COSV53374905, COSV99529669; called by muse, mutect2, varscan2
- PCDH11X | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100006772; called by muse, mutect2, varscan2
- PCDHA10 | c.1424C>A p.T475K | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100247807; called by muse, mutect2, varscan2
- PCDHA3 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793171, COSV63539275; called by muse, mutect2, varscan2
- PLEC | c.7731G>C p.Q2577H (on ENST00000322810 / NM_201380.4; = p.Q2467H on NM_000445.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as rs1554689985, COSV100511060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLTP | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99509667; called by muse, mutect2
- PLXNA2 | c.4886G>T p.G1629V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV100885149; called by muse, mutect2, varscan2
- PPM1F | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs763888472, COSV99601282; called by muse, mutect2, varscan2
- PRICKLE4 | c.208G>A p.G70R (on ENST00000359201; = p.G110R on NM_013397.6) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100138630; called by muse, mutect2, varscan2
- PRKDC | c.10282G>T p.E3428* | Nonsense Mutation (SNP) | VAF 37/69 reads (54%) | catalogued as COSV100038547, COSV58064282; called by muse, mutect2, varscan2
- PRKDC | c.10281G>T p.E3427D | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as COSV100038549; called by muse, mutect2, varscan2
- PTPRB | c.4484C>A p.A1495D | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99715957; called by muse, mutect2, varscan2
- PXDNL | c.2734G>T p.D912Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100681536, COSV62496219; called by muse, mutect2
- PYGO1 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100114486; called by muse, mutect2, varscan2
- RGS22 | c.3439A>G p.M1147V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs753883129, COSV100692998; called by muse, mutect2
- RGS22 | c.2073G>C p.K691N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100693000; called by muse, mutect2, varscan2
- RIF1 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54612602, COSV99690102; called by muse, mutect2, varscan2
- ROS1 | c.800A>T p.N267I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100876525; called by muse, mutect2, varscan2
- RWDD2B | c.943G>C p.G315R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99725528; called by muse, mutect2, varscan2
- SLC39A12 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV101069852; called by muse, mutect2
- SLC66A3 | c.148del p.L50Wfs*15 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | catalogued as COSV54466412; called by mutect2, pindel, varscan2
- SMPD3 | c.1177G>C p.G393R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99545306; called by muse, mutect2, varscan2
- SPAG17 | c.5143C>G p.R1715G | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100308022, COSV60468652, COSV60469688; called by muse, mutect2, varscan2
- SPEG | c.4060C>T p.Q1354* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100403362; called by muse, mutect2
- SPHKAP | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100763728; called by muse, mutect2, varscan2
- SPTA1 | c.2683C>A p.L895I | Missense Mutation (SNP) | VAF 135/256 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63759643; called by muse, mutect2, varscan2
- SULT1E1 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV56946153, COSV99894745, COSV99895327; called by muse, mutect2, varscan2
- SYCE1 | c.695G>T p.R232L (on ENST00000343131 / NM_001143764.3; = p.R196L on NM_130784.3) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100385704; called by muse, mutect2, varscan2
- SYNPO2 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100204933; called by muse, mutect2
- TARS2 | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs964813368, COSV100945857; called by muse, mutect2, varscan2
- TAS2R1 | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1486840476, COSV101225690, COSV66778006; called by muse, mutect2, varscan2
- THOC2 | c.4201C>G p.P1401A | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99832779; called by muse, mutect2, varscan2
- THSD7B | c.2137G>T p.V713L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99744833; called by muse, mutect2, varscan2
- TIMD4 | c.141C>A p.H47Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143159453, COSV99192499; called by muse, mutect2, varscan2
- TLR4 | c.1668A>G p.I556M (on ENST00000355622 / NM_138554.5; = p.I516M on NM_003266.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100842666; called by muse, mutect2, varscan2
- TM4SF20 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV100459972; called by muse, mutect2, varscan2
- TMC5 | c.2696G>A p.R899Q (on ENST00000396229 / NM_001105248.1; = p.R653Q on NM_024780.5) | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs527274612, COSV54902690; called by muse, mutect2, varscan2
- TRIM58 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100824894; called by muse, mutect2, varscan2
- TRIML2 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100455893; called by muse, mutect2, varscan2
- TSGA10IP | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV101598383; called by muse, mutect2, varscan2
- TSR1 | c.34C>G p.Q12E | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs750993264, COSV99279761; called by muse, mutect2, varscan2
- TTI1 | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV100989579; called by muse, mutect2, varscan2
- TTLL6 | c.1391G>A p.R464Q (on ENST00000393382 / NM_001130918.3; = p.R157Q on NM_173623.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.611); catalogued as rs202000811, COSV100938055, COSV100938212; called by muse, mutect2, varscan2
- TTN | c.82421A>G p.Y27474C (on ENST00000591111; = p.Y20050C on NM_003319.4) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | PolyPhen probably damaging (0.999); catalogued as COSV100595533; called by muse, mutect2, varscan2
- TTN | c.25286C>G p.S8429C (on ENST00000591111; = p.S7502C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | PolyPhen possibly damaging (0.767); catalogued as COSV100595535, COSV60368066; called by muse, mutect2
- TUT4 | c.2372C>G p.A791G | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV99931849; called by muse, mutect2
- UBE4A | c.1897G>T p.G633C (on ENST00000252108 / NM_001204077.2; = p.G640C on NM_004788.4) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99347886; called by muse, mutect2
- USH2A | c.9957A>T p.P3319= | Splice Region (SNP) | VAF 27/124 reads (22%) | catalogued as COSV100229413; called by muse, mutect2, varscan2
- USH2A | c.9662T>A p.V3221D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100229416; called by muse, mutect2, varscan2
- USP48 | c.1572A>G p.I524M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100379519; called by muse, mutect2, varscan2
- VPS13C | c.4322A>T p.K1441I (on ENST00000644861 / NM_020821.3; = p.K1398I on NM_017684.5) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV99827314; called by muse, mutect2, varscan2
- ZBTB38 | c.231C>G p.D77E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.224); catalogued as COSV100375353, COSV58541452; called by muse, mutect2, varscan2
- ZDHHC8 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100272622; called by muse, mutect2
- ZFAT | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100914258; called by muse, mutect2, varscan2
- ZFC3H1 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs752653262, COSV101110339; called by muse, mutect2, varscan2
- ZNF280D | c.2857C>G p.Q953E | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV50996432; called by muse, mutect2, varscan2
- ZNF33B | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100847595, COSV63943424; called by muse, mutect2, varscan2
- ZP2 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs770801322, COSV99559217; called by muse, mutect2, varscan2
- ZSCAN18 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99559108; called by muse, mutect2, varscan2
- ZSWIM2 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV99719932; called by muse, mutect2, varscan2
- ATP8B3 | c.1176del p.C393Afs*113 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- KLHL1 | c.95del p.P32Rfs*34 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- ARPC2 | c.504G>T p.V168= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99826565; called by muse, mutect2, varscan2
- C1orf141 | c.735C>T p.F245= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs267598698, COSV63992364; called by muse, mutect2, varscan2
- CATSPER1 | c.1152G>A p.Q384= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV56414122; called by muse, mutect2
- CCNQ | c.517C>T p.L173= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99367873; called by muse, mutect2, varscan2
- CDK17 | c.1164A>G p.L388= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs1565803499, COSV99702452; called by muse, mutect2, varscan2
- CPA4 | c.885C>A p.I295= | Silent (SNP) | VAF 74/169 reads (44%) | catalogued as COSV99744659; called by muse, mutect2, varscan2
- CSMD3 | c.10242A>T p.P3414= (on ENST00000297405 / NM_001363185.1; = p.P3245= on NM_052900.3) | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV99825576; called by muse, mutect2, varscan2
- DGKB | c.771T>C p.Y257= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs551396536, COSV99336635; called by muse, mutect2, varscan2
- DRD5 | c.1116G>T p.L372= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1198577668, COSV100431552; called by muse, mutect2, varscan2
- EP400 | c.7737C>T p.T2579= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100200476; called by muse, mutect2, varscan2
- FPGT | c.765G>A p.V255= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100907068; called by muse, mutect2, varscan2
- GATAD2A | c.1836C>T p.R612= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV99389664; called by muse, mutect2, varscan2
- HOXA1 | c.582C>A p.P194= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as rs751945966, COSV56065197, COSV99761011; called by muse, mutect2, varscan2
- HP | c.1215G>A p.E405= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100577455; called by muse, mutect2, varscan2
- HPSE2 | c.1023G>A p.R341= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as rs1412598558, COSV100985045; called by muse, mutect2, varscan2
- HRNR | c.5577C>A p.G1859= | Silent (SNP) | VAF 64/1528 reads (4%) | catalogued as COSV100913003; called by muse, mutect2
- KCNA5 | c.744C>T p.S248= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV52905663, COSV52905748; called by muse, mutect2, varscan2
- KCNK13 | c.1170G>C p.G390= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs749642093, COSV56414750, COSV99965513; called by muse, mutect2, varscan2
- KCNQ3 | c.921G>T p.L307= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV101195656, COSV101195750; called by muse, mutect2, varscan2
- KRTAP10-8 | c.30T>C p.Y10= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV100552015; called by muse, mutect2, varscan2
- LAMP5 | c.522C>T p.T174= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs780164560, COSV99855446; called by muse, mutect2, varscan2
- MAGEA4 | c.951C>A p.V317= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV99367298; called by muse, mutect2, varscan2
- NEUROD6 | c.840C>T p.D280= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs780201489, COSV51772738; called by muse, mutect2, varscan2
- NRXN2 | c.2583G>A p.E861= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99632605; called by muse, mutect2, varscan2
- OR10K1 | c.273C>A p.T91= | Silent (SNP) | VAF 45/284 reads (16%) | catalogued as rs1176719574, COSV56873279; called by muse, mutect2, varscan2
- OVCH1 | c.1998C>T p.A666= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100548249; called by muse, mutect2, varscan2
- PDGFC | c.792G>A p.K264= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV56856134, COSV56856213; called by muse, mutect2, varscan2
- PHEX | c.1167C>T p.F389= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV101039404; called by muse, mutect2, varscan2
- PLAU | c.393C>G p.P131= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV101032249; called by muse, mutect2, varscan2
- PNKD | c.729C>T p.Y243= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99282176; called by muse, mutect2, varscan2
- POLE | c.3036C>T p.Y1012= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs1060504062, COSV100265442; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPDPFL | c.156C>A p.S52= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57461897; called by muse, mutect2, varscan2
- PPRC1 | c.4236C>T p.A1412= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs762078980, COSV99531322; called by muse, mutect2, varscan2
- PRSS55 | c.114C>A p.A38= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100153632; called by muse, mutect2
- RPL19 | c.90T>C p.N30= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99841366; called by muse, mutect2, varscan2
- SALL3 | c.2862G>T p.A954= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV101609941; called by muse, mutect2, varscan2
- SAMD9L | c.1023G>C p.L341= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV100560343; called by muse, mutect2, varscan2
- SEMA7A | c.1572C>T p.S524= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs145844323, COSV99984588; called by muse, mutect2, varscan2
- SLA2 | c.117C>T p.A39= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99481251; called by muse, mutect2, varscan2
- SLITRK3 | c.2037C>A p.L679= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99578539; called by muse, mutect2, varscan2
- ST6GAL2 | c.189C>T p.G63= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV64527677, COSV64527700; called by muse, mutect2
- TCF20 | c.1815G>A p.G605= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100166282; called by muse, mutect2, varscan2
- TDRKH | c.1191C>T p.C397= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- TUBA3C | c.1227G>T p.V409= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as rs1238928009, COSV101313835; called by muse, mutect2, varscan2
- UBAP2L | c.3207G>T p.P1069= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV99670565; called by muse, mutect2, varscan2
- UBE4A | c.1896G>A p.L632= (on ENST00000252108 / NM_001204077.2; = p.L639= on NM_004788.4) | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV52806231, COSV99347884; called by muse, mutect2
- UNC13A | c.1449C>T p.G483= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs746066343, COSV53207525; called by muse, mutect2, varscan2
- ZBTB41 | c.969A>G p.Q323= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV100962837; called by muse, mutect2, varscan2
- ZFP42 | c.258G>C p.L86= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100478639; called by muse, mutect2, varscan2
- ZNF326 | c.402A>C p.A134= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV100437903; called by muse, mutect2, varscan2
- ZNF536 | c.534G>C p.R178= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100834709; called by muse, mutect2
- ZNF699 | c.1164G>A p.E388= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100426826; called by muse, mutect2, varscan2
- ZNF781 | c.651C>G p.L217= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs150275573; called by muse, mutect2, varscan2
- CLCA3P | n.698C>A | RNA (SNP) | VAF 19/63 reads (30%) | catalogued as rs746642744; called by muse, mutect2, varscan2
- EIF4A1 | c.515-141G>A | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as rs1216931058, COSV99548741; called by muse, mutect2, varscan2
- PI4KB | c.-17del | 5'UTR (DEL) | VAF 10/47 reads (21%) | catalogued as COSV55016259; called by mutect2, pindel
- RBAK | c.-161G>C | 5'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100806557; called by muse, mutect2, varscan2
- TTN | c.10360+5456C>T | Intron (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100595536; called by muse, mutect2, varscan2
